Somatic mutation profile of tumor specimen MMRF_1223_4_BM_CD138pos (aliquot MMRF_1223_4_BM_CD138pos_T1_KHS5U_L11073) from MMRF case MMRF_1223, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.7 years (13,027 days).
Specimen MMRF_1223_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7c4d13f-cf2c-4b6e-aa46-60ba3914c956.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1223_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1223_2_PB_Whole_C3_KBS5U_L05821; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45f6c1d4-edb6-4ddd-8ae5-9d9993b8aeb8

The open-access MAF lists 50 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 11, Silent 5, Intron 3, 3'Flank 3, 5'UTR 3, Splice Region 2, Nonsense Mutation 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C10orf71 | c.3806C>T p.A1269V | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs924510693, COSV60507375; called by muse, mutect2, varscan2
- CCDC114 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759075558; called by muse, mutect2, varscan2
- CNTN4 | c.2281G>A p.V761M | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763159501, COSV61871407, COSV61875748; called by muse, mutect2, varscan2
- CR1 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs571542796; called by muse, mutect2, varscan2
- GAS2L2 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 174/385 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs782029559; called by muse, mutect2, varscan2
- GRAMD1A | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs201696171, COSV58765928; called by muse, mutect2
- IGKV1-5 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs555311313; called by muse, varscan2
- IGKV1-5 | c.57T>C p.G19= | Splice Region (SNP) | VAF 41/49 reads (84%) | catalogued as rs530103870; called by muse, mutect2, varscan2
- IGKV1-8 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 72/85 reads (85%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs376991397; called by muse, mutect2, varscan2
- KCNJ5 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 181/370 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs142140011; called by muse, mutect2, varscan2
- MYH14 | c.4315C>T p.R1439C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867601827, COSV51809446; called by muse, mutect2, varscan2
- PRPF8 | c.4498G>A p.G1500R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59268806; called by muse, mutect2, varscan2
- SLC6A20 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV62071180; called by muse, mutect2, varscan2
- SYNE1 | c.3850C>T p.R1284W (on ENST00000367255 / NM_182961.4; = p.R1291W on NM_033071.3) | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs140780725; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ADK | c.220A>T p.K74* (on ENST00000286621; = p.K57* on NM_001123.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.603+7G>T | Splice Region (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 18/22 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- IL20RA | c.1334C>G p.T445R | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCTD3 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MEPE | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 171/382 reads (45%) | called by muse, mutect2, varscan2
- P4HB | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RASGRF2 | c.2615C>G p.A872G | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UGT3A2 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RECQL4 | c.2208C>T p.A736= | Silent (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- SEC31A | c.2266T>C p.L756= (on ENST00000355196 / NM_001318120.1; = p.L717= on NM_016211.4) | Silent (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- SORBS2 | c.1170C>T p.D390= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs1232046457; called by muse, mutect2, varscan2
- SOX6 | c.1509G>A p.A503= (on ENST00000528429 / NM_001145819.2; = p.A476= on NM_017508.3) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs373068695; called by muse, mutect2, varscan2
- ZNF600 | c.450A>T p.P150= | Silent (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- AC124067.3 | n.11G>A | RNA (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- C18orf54 | c.*1046G>T | 3'UTR (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- CPZ | c.*47C>T | 3'UTR (SNP) | VAF 14/24 reads (58%) | catalogued as rs751996171; called by muse, mutect2, varscan2
- CYFIP2 | chr5:157395417 A>T | 3'Flank (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- DIPK2A | c.657+250T>C | Intron (SNP) | VAF 144/330 reads (44%) | called by muse, mutect2, varscan2
- FAM76B | c.*2037T>A | 3'UTR (SNP) | VAF 19/63 reads (30%) | catalogued as rs1313908741; called by muse, mutect2, varscan2
- FHAD1 | c.4122+5879C>T | Intron (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- GRID1 | c.*1840G>T | 3'UTR (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- HPS3 | c.-14C>T | 5'UTR (SNP) | VAF 16/25 reads (64%) | catalogued as rs1189093183; called by muse, mutect2, varscan2
- KCNA6 | c.-213C>A | 5'UTR (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- LARS2 | chr3:45549481 A>G | 3'Flank (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- MAGIX | chrX:49167496 C>A | 3'Flank (SNP) | VAF 64/70 reads (91%) | catalogued as COSV100890549; called by muse, mutect2, varscan2
- PTCHD1 | c.*7323C>T | 3'UTR (SNP) | VAF 38/41 reads (93%) | called by muse, mutect2, varscan2
- RAB17 | c.158-131C>T | Intron (SNP) | VAF 3/35 reads (9%) | catalogued as rs1232289792; called by muse, mutect2
- RNF115 | c.*980A>T | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- RTP5 | c.*163C>T | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- SGO1 | c.*206C>T | 3'UTR (SNP) | VAF 43/105 reads (41%) | catalogued as rs753900344; called by muse, mutect2, varscan2
- SMU1 | c.*3363A>G | 3'UTR (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- SMU1 | c.*3361T>C | 3'UTR (SNP) | VAF 5/107 reads (5%) | catalogued as rs1431428843; called by muse, mutect2
- SORL1 | c.*4061dup | 3'UTR (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- THUMPD1 | c.-168C>A | 5'UTR (SNP) | VAF 41/237 reads (17%) | called by muse, mutect2, varscan2
